Somatic mutation profile of tumor specimen 0DEQWS from CCDI case PBBRBK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.7 years (3,538 days).
Specimen 0DEQWS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18862371-009e-45dd-aed0-4a063e01f8eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEQWU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6385ae40-2bbf-4c03-9a03-dcb6535bebdc

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLPPR4 | c.815C>G p.T272R | Missense Mutation (SNP) | VAF 34/631 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100926876; called by muse, mutect2
- PTPRU | c.2377G>A p.V793I | Missense Mutation (SNP) | VAF 34/459 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs376574571; called by muse, mutect2
- ANKRD52 | c.1725C>G p.N575K | Missense Mutation (SNP) | VAF 80/459 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- MICAL1 | c.2113T>C p.Y705H | Missense Mutation (SNP) | VAF 82/340 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- RTL10 | c.980del p.T327Kfs*16 | Frame Shift Del (DEL) | VAF 118/400 reads (30%) | called by mutect2, varscan2
- SENP6 | c.26G>A p.S9N | Missense Mutation (SNP) | VAF 141/438 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SERPINF1 | c.440-79C>A | Intron (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
